Somatic mutation profile of tumor specimen TCGA-DJ-A4V2-01A (aliquot TCGA-DJ-A4V2-01A-11D-A257-08) from TCGA case TCGA-DJ-A4V2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.7 years (14,126 days).
Specimen TCGA-DJ-A4V2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a55728e-5858-4ed4-b15b-97ad07ab76c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4V2-10A (Blood Derived Normal), aliquot TCGA-DJ-A4V2-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/075f113b-892f-4e3a-8c70-e836ba5d28ac

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATR | c.3217C>T p.Q1073* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100638475, COSV63384679; called by muse, mutect2, varscan2
- GJD2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 42/178 reads (24%) | catalogued as rs749647277, COSV51747639; called by muse, mutect2, varscan2
- PCDH11X | c.1805A>G p.N602S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015312; called by muse, mutect2
- TDO2 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV72232680; called by muse, mutect2, varscan2
- WAC | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100611193; called by muse, mutect2
- ACKR2 | c.486G>T p.L162= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV56179754; called by muse, mutect2, varscan2
- GPR179 | c.2460C>T p.S820= (on ENST00000621958; = p.S819= on NM_001004334.4) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs769007049; called by muse, mutect2, varscan2
